CCDI case PBBXKJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/3831db93-3652-4ba5-a4bc-4a556d4570b6

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 2.8 years (1,019 days).

Biospecimens (3 samples)
- Sample 0DJVP2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJVPD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJVPO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
